Somatic mutation profile of tumor specimen TCGA-02-2470-01A (aliquot TCGA-02-2470-01A-01D-1494-08) from TCGA case TCGA-02-2470, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.6 years (21,021 days).
Specimen TCGA-02-2470-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cddd8169-648d-4a7d-af2f-ad2a893b0f1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-02-2470-10A (Blood Derived Normal), aliquot TCGA-02-2470-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39bc8e0a-7e9d-4d5e-b0cc-3c3a5d3cba6d

The open-access MAF lists 59 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 12, Nonsense Mutation 2, 5'Flank 2, Splice Site 1, Intron 1, Splice Region 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 110/212 reads (52%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- AC013489.1 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs1265060262, COSV51550247; called by muse, varscan2
- ANO3 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 95/369 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as rs566590577, COSV56781737; called by muse, mutect2, varscan2
- BPIFB2 | c.585C>G p.N195K | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV50063189; called by muse, mutect2, varscan2
- C14orf39 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as COSV58779397, COSV58779744; called by muse, mutect2, varscan2
- CAPN1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs748491783, COSV54196856; called by muse, mutect2, varscan2
- CATSPERD | c.1352A>G p.N451S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.429); catalogued as COSV58464369; called by muse, mutect2, varscan2
- CD96 | c.417C>T p.H139= | Splice Region (SNP) | VAF 20/81 reads (25%) | catalogued as rs368182013; called by muse, mutect2, varscan2
- CT55 | c.368A>G p.E123G | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV52277163; called by muse, mutect2, varscan2
- CTAGE1 | c.2205A>T p.R735S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV66942964; called by muse, mutect2, varscan2
- DRC7 | c.1822G>A p.V608M | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.632); catalogued as COSV61053195; called by muse, mutect2, varscan2
- ERGIC1 | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV58595442; called by muse, mutect2, varscan2
- FGF14 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); catalogued as rs757879324, COSV65935613; called by muse, mutect2, varscan2
- GABRA4 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51923029; called by muse, mutect2, varscan2
- JCAD | c.3317C>T p.A1106V | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as rs772260546, COSV64757970; called by muse, mutect2, varscan2
- KCNA2 | c.450G>T p.W150C | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60369206; called by muse, mutect2, varscan2
- MAGEB18 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.291); catalogued as rs1190740592, COSV57463420; called by muse, mutect2, varscan2
- MATK | c.653C>T p.S218L (on ENST00000310132 / NM_139355.3; = p.S219L on NM_002378.4) | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as rs767457416, COSV59553265; called by muse, mutect2, varscan2
- MELK | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 270/564 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53197176; called by muse, varscan2
- MX2 | c.1472A>G p.E491G | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV58095214; called by muse, mutect2, varscan2
- NEFM | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55330599; called by muse, mutect2, varscan2
- NKAIN1 | c.193-2A>G p.X65_splice | Splice Site (SNP) | VAF 6/21 reads (29%) | catalogued as rs1296402468, COSV55273897; called by muse, mutect2
- OR10V1 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.444); catalogued as rs144835634; called by muse, mutect2, varscan2
- OR5D13 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs369729738, COSV62332785; called by muse, varscan2
- PPP1R16B | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55374490; called by muse, mutect2, varscan2
- PSME4 | c.5275C>T p.R1759C | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV66363339; called by muse, mutect2, varscan2
- RAPGEF3 | c.1017G>T p.K339N (on ENST00000389212; = p.K297N on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV50198682; called by muse, mutect2, varscan2
- RFX6 | c.578A>C p.Y193S | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV60583598; called by muse, mutect2, varscan2
- RIMBP2 | c.2489G>A p.R830H | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1020820815, COSV55464560; called by muse, mutect2, varscan2
- RYR2 | c.1109T>A p.L370Q | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63664831; called by muse, mutect2, varscan2
- SMG8 | c.2867T>G p.F956C | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56284070; called by muse, mutect2, varscan2
- SRRM4 | c.1220C>G p.S407C | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV57409399; called by muse, mutect2, varscan2
- SSTR4 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs745839410, COSV54797106; called by muse, mutect2, varscan2
- STAM2 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV55729815; called by muse, mutect2, varscan2
- SYNJ2 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs772199451, COSV62895768; called by muse, mutect2, varscan2
- TDRD9 | c.3962A>C p.Q1321P | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV59142800; called by muse, mutect2, varscan2
- TNFRSF11A | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as rs376096275; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPO | c.1399G>A p.V467M | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.261); catalogued as rs373267637; called by muse, mutect2, varscan2
- WDR70 | c.816T>G p.Y272* | Nonsense Mutation (SNP) | VAF 40/175 reads (23%) | catalogued as COSV54267265; called by muse, mutect2, varscan2
- XYLB | c.655A>G p.M219V | Missense Mutation (SNP) | VAF 78/463 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52911693; called by muse, mutect2, varscan2
- ZNF526 | c.1789C>G p.R597G | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV55898496; called by muse, mutect2, varscan2
- ZNF606 | c.1068C>G p.F356L | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs772271108, COSV100357230, COSV62045291; called by muse, mutect2, varscan2
- AC013489.1 | c.958_960del p.F320del | In Frame Del (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- NFIX | c.1248del p.G417Dfs*46 (on ENST00000592199 / NM_001365902.3; = p.G417Dfs*47 on NM_002501.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- C1QTNF5 | c.546C>T p.F182= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV60990603; called by muse, mutect2, varscan2
- DLK1 | c.1137C>T p.G379= | Silent (SNP) | VAF 29/172 reads (17%) | catalogued as rs753638016, COSV57990660; called by muse, mutect2, varscan2
- ELOA2 | c.1233A>G p.Q411= | Silent (SNP) | VAF 52/237 reads (22%) | catalogued as rs1480913404, COSV55294183; called by muse, mutect2, varscan2
- IL1R2 | c.748C>T p.L250= | Silent (SNP) | VAF 24/308 reads (8%) | catalogued as COSV60205817; called by muse, mutect2
- ITGAX | c.333C>T p.T111= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs761480055, COSV51642021; called by muse, mutect2, varscan2
- NPHS1 | c.852G>A p.P284= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs763233132, COSV62286544; called by muse, mutect2, varscan2
- PARP12 | c.1671G>A p.V557= | Silent (SNP) | VAF 26/178 reads (15%) | catalogued as COSV54932424; called by muse, mutect2, varscan2
- PDHA2 | c.585C>T p.G195= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as rs550687466, COSV54777335, COSV54777456; called by muse, mutect2, varscan2
- SPATA31A1 | c.1176G>T p.L392= | Silent (SNP) | VAF 109/304 reads (36%) | called by muse, mutect2, varscan2
- STAM | c.450A>G p.A150= | Silent (SNP) | VAF 113/210 reads (54%) | catalogued as COSV66324951; called by muse, mutect2, varscan2
- TGM5 | c.330G>A p.A110= | Silent (SNP) | VAF 37/121 reads (31%) | catalogued as COSV55008756; called by muse, mutect2, varscan2
- TJP3 | c.186C>T p.N62= | Silent (SNP) | VAF 58/241 reads (24%) | catalogued as rs751459511, COSV53661000; called by muse, mutect2, varscan2
- DLG4 | chr17:7218632 C>G | 5'Flank (SNP) | VAF 3/8 reads (38%) | catalogued as COSV57236848; called by muse, mutect2
- NEBL-AS1 | chr10:21172392 T>C | 5'Flank (SNP) | VAF 39/89 reads (44%) | catalogued as COSV68841139; called by muse, mutect2, varscan2
- RPL5 | c.528-103A>C | Intron (SNP) | VAF 9/290 reads (3%) | catalogued as COSV100240490; called by muse, mutect2
